Somatic mutation profile of tumor specimen 4a25e3da-2226-4e23-a595-c11709 (aliquot 4a25e3da-2226-4e23-a595-c11709_D6_1) from CPTAC case 01BR040, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 40.0 years (14,599 days).
Specimen 4a25e3da-2226-4e23-a595-c11709: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b8b6a53-d2f9-457f-8533-431396e0ecdc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 079a67ab-c81a-4fcb-a976-2d2fb6 (Blood Derived Normal), aliquot 079a67ab-c81a-4fcb-a976-2d2fb6_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32fd1bf3-3511-47ea-9a59-da717c2f1d41

The open-access MAF lists 38 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 6, Intron 4, Frame Shift Del 2, Nonsense Mutation 1, Splice Region 1, 5'Flank 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FANCG | c.1715G>A p.W572* | Nonsense Mutation (SNP) | VAF 219/522 reads (42%) | catalogued as CM002774; called by mutect2, varscan2
- MYOG | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 20/464 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1254393566; called by muse, mutect2
- NSD1 | c.6328C>A p.Q2110K | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.056); catalogued as CM1211959; called by muse, mutect2, varscan2
- PSMB7 | c.393C>T p.F131= | Splice Region (SNP) | VAF 7/23 reads (30%) | catalogued as COSV52332921; called by muse, mutect2, varscan2
- PSMD12 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV62066374; called by muse, mutect2, varscan2
- RIPK4 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 176/482 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773242499, COSV60185559; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC1A2 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.085); catalogued as rs1400780690; called by muse, mutect2
- SPTB | c.5482G>A p.A1828T | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as rs370441240; called by muse, mutect2, varscan2
- TBX15 | c.842C>T p.T281M (on ENST00000369429 / NM_001330677.2; = p.T175M on NM_152380.3) | Missense Mutation (SNP) | VAF 78/263 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1350358852, COSV99254981; called by muse, mutect2, varscan2
- TMEM132C | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs759171315, COSV100174945; called by muse, mutect2, varscan2
- VPS13B | c.1913C>G p.T638S | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV62022924; called by muse, mutect2, varscan2
- ASCC3 | c.4706_4709del p.R1569Lfs*6 | Frame Shift Del (DEL) | VAF 100/337 reads (30%) | called by mutect2, pindel*, varscan2*
- BTAF1 | c.2003C>G p.A668G | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- CD300C | c.283G>T p.V95L | Missense Mutation (SNP) | VAF 55/376 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP46 | c.2731G>A p.D911N | Missense Mutation (SNP) | VAF 53/279 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- COL17A1 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 99/540 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CUL7 | c.2517G>C p.K839N | Missense Mutation (SNP) | VAF 61/609 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MYO18A | c.4072A>G p.I1358V | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NCOA7 | c.1586A>C p.K529T | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- NFIX | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- PCDH1 | c.3184G>T p.G1062C | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PTOV1 | c.755T>C p.I252T | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STAT5B | c.1411C>T p.H471Y | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TP53 | c.865_867delinsT p.L289Sfs*16 | Frame Shift Del (DEL) | VAF 47/258 reads (18%) | called by pindel, varscan2*
- ZC3H13 | c.4791C>G p.F1597L (on ENST00000242848 / NM_001330565.2; = p.F1598L on NM_001076788.2 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- ANKRD36C | c.4560T>C p.A1520= | Silent (SNP) | VAF 39/289 reads (13%) | called by muse, mutect2, varscan2
- CUBN | c.10728C>T p.N3576= | Silent (SNP) | VAF 36/332 reads (11%) | catalogued as rs368511477; called by muse, mutect2, varscan2
- DAPK2 | c.1107C>G p.T369= | Silent (SNP) | VAF 20/54 reads (37%) | called by mutect2, varscan2
- DNMBP | c.1803G>T p.L601= | Silent (SNP) | VAF 31/160 reads (19%) | called by mutect2, varscan2
- PDZD2 | c.1503C>T p.L501= | Silent (SNP) | VAF 18/139 reads (13%) | called by muse, mutect2, varscan2
- UGCG | c.45G>A p.G15= | Silent (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499063 C>T | 5'Flank (SNP) | VAF 16/47 reads (34%) | catalogued as rs373733194; called by muse, mutect2, varscan2
- DLG2 | c.1978+3745G>A | Intron (SNP) | VAF 20/99 reads (20%) | catalogued as rs1335244295; called by muse, mutect2, varscan2
- KRT18 | c.-28T>A | 5'UTR (SNP) | VAF 22/80 reads (28%) | called by muse, mutect2, varscan2
- MIR369 | n.68C>G | RNA (SNP) | VAF 33/397 reads (8%) | called by muse, mutect2
- SLC30A7 | c.1084-2508C>T | Intron (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- SYNE1 | c.3027+24A>G | Intron (SNP) | VAF 33/180 reads (18%) | called by muse, mutect2, varscan2
- TRPM4 | c.3329-10G>A | Intron (SNP) | VAF 46/251 reads (18%) | catalogued as rs764962434, COSV53261523; called by muse, mutect2, varscan2
